Gene-level copy-number profile of tumor specimen TCGA-13-1405-01A from TCGA case TCGA-13-1405, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.9 years (18,218 days).
Specimen TCGA-13-1405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ca2c5fe5-72fc-4cb1-b26c-708e72bf03a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1405-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d40e15a-905a-4df8-9906-262c5f4810e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 24,496; copy number 2: 32,753; copy number 3: 2,511; copy number 4: 18; copy number 5: 30; copy number 6: 8; copy number 8: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1405-01A-01D-0452-01): tumor purity 0.68, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,269,653–180,566,523, 5 genes, copy number 6 (within-gene range 4–6): ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA.
- chr2:28,633,282–28,802,940, 4 genes, copy number 5: AC074011.1, RNA5SP89, AC092164.1, PPP1CB.
- chr4:25,529,177–25,623,601, 3 genes, copy number 8: AC105290.1, RNU7-126P, AC092436.1.
- chr11:13,784,017–13,924,863, 5 genes, copy number 5: LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683.
- chr17:77,198,950–77,281,897, 3 genes, copy number 6: CYCSP40, SEPTIN9-DT, AC068594.1.
- chr19:9,019,344–9,126,950, 7 genes, copy number 5: BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3.
- chr22:17,787,649–18,024,561, 1 gene, copy number 5 (within-gene range 3–5): MICAL3.
- chr22:17,980,868–18,177,397, 13 genes, copy number 5 (within-gene range 2–5): MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18.

Autosomal genes at a single copy (total copy number 1): 22,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
